Somatic mutation profile of tumor specimen TCGA-VQ-A928-01A (aliquot TCGA-VQ-A928-01A-11D-A410-08) from TCGA case TCGA-VQ-A928, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 49.4 years (18,058 days).
Specimen TCGA-VQ-A928-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4a732c5-586f-4738-a4fa-d340520a5f1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A928-10A (Blood Derived Normal), aliquot TCGA-VQ-A928-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebe6a435-09e5-43b4-a8b6-566ec0ad92d3

The open-access MAF lists 66 somatic variants for this specimen: 50 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 15, Frame Shift Del 2, In Frame Ins 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABRA | c.692T>A p.L231H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as COSV100357442, COSV100357636; called by muse, mutect2, varscan2
- AP2A1 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs571345662, COSV62818696; called by muse, mutect2, varscan2
- ASAP2 | c.1754A>G p.D585G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752573155, COSV99855638; called by muse, mutect2, varscan2
- ASTN1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs767625006, COSV56070602; called by muse, mutect2, varscan2
- AVPI1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs775549165, COSV101033265; called by muse, mutect2, varscan2
- CACNA1G | c.5002C>T p.R1668C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1369128414, COSV61730920; called by muse, mutect2, varscan2
- CCDC88A | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs769621745, COSV55069328; called by muse, mutect2, varscan2
- CD5L | c.619T>A p.S207T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs548320729, COSV63822007; called by muse, mutect2, varscan2
- CDC45 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353770557, COSV99596366; called by muse, mutect2, varscan2
- CDH10 | c.773C>G p.T258R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100049800, COSV52569461; called by muse, mutect2, varscan2
- CEP126 | c.645C>A p.F215L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV99680483; called by muse, mutect2
- CNTNAP1 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1378367385, COSV99226062; called by muse, mutect2, varscan2
- COPB1 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99999209; called by muse, mutect2, varscan2
- DENND2A | c.1419C>G p.N473K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV99325445; called by muse, mutect2, varscan2
- DNAJC5G | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99940476; called by muse, mutect2
- EBF2 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101282074, COSV68780367; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2357G>T p.G786V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748497361, COSV100668323; called by muse, mutect2, varscan2
- ELAVL4 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100836492, COSV63915579; called by muse, mutect2, varscan2
- GRM4 | c.2056C>A p.R686S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV100945623; called by muse, mutect2, varscan2
- KIFC1 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV100997072; called by muse, mutect2, varscan2
- MCF2L | c.1244G>A p.G415D (on ENST00000375608; = p.G383D on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100982057; called by muse, mutect2, varscan2
- MCM5 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99331411; called by muse, mutect2, varscan2
- MEGF10 | c.1742G>T p.C581F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384735890, COSV99174673; called by muse, mutect2, varscan2
- MIA2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV99696590; called by muse, mutect2, varscan2
- MLST8 | c.480C>A p.D160E | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as COSV100063035; called by muse, mutect2, varscan2
- MUC6 | c.6611C>T p.A2204V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as COSV101424375; called by muse, mutect2, varscan2
- NID1 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs1054231294, COSV99936887; called by muse, mutect2
- NTM | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs148152724; called by muse, mutect2, varscan2
- NUCB2 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100082541; called by muse, mutect2, varscan2
- OR1S1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as COSV100515212; called by muse, mutect2, varscan2
- OR51G2 | c.85C>A p.H29N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV100432020; called by muse, mutect2, varscan2
- OR52E4 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100389119; called by muse, mutect2, varscan2
- OR5D13 | c.641T>G p.I214S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV100686652, COSV62334012; called by muse, mutect2, varscan2
- PCDH15 | c.4133T>A p.L1378* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV57343534; called by muse, mutect2, varscan2
- PCDHA12 | c.2035T>A p.S679T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.199); catalogued as COSV99164920; called by muse, mutect2, varscan2
- PCDHAC2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99144162; called by muse, mutect2, varscan2
- PCLO | c.1691G>C p.G564A | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100426653; called by muse, mutect2
- PPEF1 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1480343562, COSV62995001; called by muse, mutect2, varscan2
- SBNO1 | c.3682A>G p.K1228E (on ENST00000420886; = p.K1227E on NM_018183.5) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.262); catalogued as COSV99928607; called by muse, mutect2, varscan2
- SCG2 | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.552); catalogued as COSV59539757; called by muse, mutect2, varscan2
- TNFSF13B | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV101022309; called by muse, mutect2, varscan2
- USP17L2 | c.87T>A p.F29L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100414498; called by muse, mutect2, varscan2
- VEGFC | c.404A>G p.E135G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99709328; called by muse, mutect2, varscan2
- VWA5A | c.2299G>T p.V767F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs778729416, COSV100827682; called by mutect2, varscan2
- ZNF141 | c.1157A>C p.K386T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV99549342; called by muse, mutect2, varscan2
- ZNF417 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.17); catalogued as COSV100364041; called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7440_7441insTTA p.I2480_P2481insL | In Frame Ins (INS) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- GGA1 | c.373_382del p.G125Rfs*3 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- MRPL45 | c.693G>C p.L231F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SRCAP | c.9397_9424del p.T3133Gfs*28 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel
- ACTN2 | c.1821C>A p.L607= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100856487; called by muse, mutect2, varscan2
- ATP10A | c.2328G>T p.L776= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100790750; called by muse, mutect2
- CAMSAP2 | c.4278T>C p.T1426= (on ENST00000236925 / NM_001297707.2; = p.T1415= on NM_203459.3) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99372752; called by muse, mutect2, varscan2
- CLDN14 | c.675G>T p.V225= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100578294; called by muse, mutect2
- EPHA2 | c.225C>T p.G75= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100626003; called by muse, varscan2
- IFNB1 | c.42C>T p.C14= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV101207768; called by muse, mutect2, varscan2
- LIFR | c.1146T>A p.L382= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99663068, COSV99664457; called by muse, mutect2, varscan2
- LPP | c.1641G>A p.P547= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100446178, COSV57093502; called by muse, mutect2
- NEUROG3 | c.558G>A p.A186= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs775461471, COSV54343041; called by muse, mutect2, varscan2
- PCDHB13 | c.1896G>A p.E632= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99506592; called by muse, mutect2
- PCDHB3 | c.1962C>T p.A654= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV99164116; called by muse, mutect2, varscan2
- SGCZ | c.177C>T p.T59= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs775777311, COSV66021770; called by muse, mutect2, varscan2
- SLC35D1 | c.90G>A p.G30= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV52430687, COSV99337917; called by muse, mutect2, varscan2
- SRSF11 | c.90C>T p.G30= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as rs1343312723, COSV100918100; called by muse, mutect2
- ZHX1 | c.1467C>G p.P489= | Silent (SNP) | VAF 15/169 reads (9%) | called by muse, mutect2
- FRMPD2B | n.617C>T | RNA (SNP) | VAF 74/196 reads (38%) | catalogued as rs1173170842; called by muse, mutect2, varscan2
